Somatic mutation profile of tumor specimen 0DHZS8 from CCDI case PBBUFF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.0 years (1,455 days).
Specimen 0DHZS8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1147915f-a418-4222-a8ec-e595f6c93c24.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHZRT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c126840-467d-4082-85db-34ac5c10080a

The open-access MAF lists 21 somatic variants for this specimen: 13 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 6, 5'UTR 2, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEP120 | c.2358G>C p.Q786H | Missense Mutation (SNP) | VAF 40/1215 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); catalogued as COSV100071276; called by muse, mutect2
- CFAP47 | c.3099+1G>A p.X1033_splice | Splice Site (SNP) | VAF 304/309 reads (98%) | catalogued as COSV52892927; called by muse, mutect2, varscan2
- CHDH | c.179C>T p.T60M | Missense Mutation (SNP) | VAF 28/458 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs947955144; called by muse, mutect2
- CHL1 | c.449T>C p.V150A | Missense Mutation (SNP) | VAF 36/1506 reads (2%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV99852208; called by muse, mutect2
- DDC | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 84/2044 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201828034; ClinVar: uncertain significance; called by muse, mutect2
- FIBIN | c.510G>C p.R170S | Missense Mutation (SNP) | VAF 30/886 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.046); catalogued as COSV59412526; called by muse, mutect2
- ATP8B4 | c.3464C>T p.P1155L | Missense Mutation (SNP) | VAF 34/883 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2
- EFNA2 | c.149C>A p.A50E | Missense Mutation (SNP) | VAF 767/1193 reads (64%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EVC | c.2097+8C>A | Splice Region (SNP) | VAF 70/898 reads (8%) | called by muse, mutect2
- OR5D13 | c.716C>T p.T239I | Missense Mutation (SNP) | VAF 36/1314 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by muse, mutect2
- POLA1 | c.3545A>C p.D1182A | Missense Mutation (SNP) | VAF 18/668 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- RARS1 | c.13G>A p.V5M | Missense Mutation (SNP) | VAF 38/658 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.246); called by muse, mutect2
- SPI1 | c.432G>T p.E144D | Missense Mutation (SNP) | VAF 22/640 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CDRT15 | c.105A>G p.R35= | Silent (SNP) | VAF 54/1328 reads (4%) | called by muse, mutect2
- CRLF2 | c.474C>A p.T158= | Silent (SNP) | VAF 57/933 reads (6%) | catalogued as COSV67493621; called by muse, mutect2
- KRT6A | c.378C>A p.G126= | Silent (SNP) | VAF 159/794 reads (20%) | catalogued as COSV100416650; called by muse, mutect2, varscan2
- NRXN2 | c.2523C>T p.N841= | Silent (SNP) | VAF 51/942 reads (5%) | catalogued as rs1423317973, COSV55450337, COSV55453977; called by muse, mutect2
- SYNM | c.1158G>C p.T386= | Silent (SNP) | VAF 34/1402 reads (2%) | called by muse, mutect2
- TIE1 | c.2841A>T p.T947= | Silent (SNP) | VAF 666/1104 reads (60%) | catalogued as COSV65250427; called by muse, mutect2, varscan2
- OR1C1 | c.-48G>T | 5'UTR (SNP) | VAF 23/366 reads (6%) | catalogued as COSV101376296; called by muse, mutect2
- TLR1 | c.-25C>T | 5'UTR (SNP) | VAF 54/848 reads (6%) | catalogued as rs1163757249; called by muse, mutect2
